Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5004, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5004-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA - BP - 5004

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: Kidney, right; partial nephrectomy

DIAGNOSIS:

1. Kidney, right; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion is also not identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Cortical scars, focal interstitial chronic inflammation, and mild arteriosclerotic changes.

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "right kidney tumor" and consists of a piece of kidney measuring 3.6 x 2.5 x 2.5 cm. The external surface is inked in black and the specimen is serially sectioned to reveal a 3 cm yellow hemorrhagic well-circumscribed mass located 0.5 cm from the nearest section margin. The uninvolved renal parenchyma is unremarkable. A representative section is submitted frozen section consultation. Representative sections are submitted.

Summary of sections:

FSC-- frozen section control

M-- margin

T-- tumor

UK-- uninvolved kidney

Summary of Sections:

Part 1: Kidney, right; partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	m	1
3	t	3
1	uk	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL TUMOR.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file bbb5575e-e332-4eb0-8a79-c6c4404b24e6 (TCGA-BP-5004.D0555415-7155-489C-89F0-B6783B088E00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).